Somatic mutation profile of tumor specimen 0DGWOI from CCDI case PBBTVN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Myeloid sarcoma; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 2.1 years (779 days).
Specimen 0DGWOI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6d7cc87-005b-40b9-8e7b-c3a6ae9f9905.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGWO8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5a9bb1b-5a7c-41b2-8ece-2e3121b49619

The open-access MAF lists 33 somatic variants for this specimen: 23 protein-altering or splice-affecting, 2 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Intron 4, Silent 2, Nonsense Mutation 2, 3'UTR 2, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1G | c.3487T>C p.S1163P | Missense Mutation (SNP) | VAF 110/299 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs748267679; called by muse, mutect2, varscan2
- CDH9 | c.131A>C p.D44A | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV50408082; called by muse, mutect2
- CHIC1 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 77/281 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs867169912; called by muse, mutect2, varscan2
- CIITA | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 196/486 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs751075993, COSV100162636; called by muse, mutect2, varscan2
- DSCAM | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 163/393 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs755881168, COSV68024346; called by muse, mutect2, varscan2
- HID1 | c.2290G>A p.V764I | Missense Mutation (SNP) | VAF 199/477 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as rs776593846, COSV60912697; called by muse, mutect2, varscan2
- OTUD6A | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 194/531 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372088322, COSV57974206; called by muse, mutect2, varscan2
- PCDH15 | c.4262C>T p.A1421V | Missense Mutation (SNP) | VAF 200/677 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.21); catalogued as rs1329914600, COSV57262088; called by muse, mutect2, varscan2
- SELENOP | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 153/386 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs764096154, COSV62793318; called by muse, mutect2, varscan2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, mutect2
- SPOCK3 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 41/565 reads (7%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.992); catalogued as rs747392218; called by muse, mutect2
- TRIOBP | c.4159C>T p.R1387W | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as rs370108541; called by muse, mutect2
- ABCC11 | c.1960A>T p.I654F | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, varscan2
- AL592490.1 | c.2710G>T p.V904F | Missense Mutation (SNP) | VAF 128/151 reads (85%) | SIFT tolerated (0.09); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- ANK1 | c.5014C>A p.L1672I | Missense Mutation (SNP) | VAF 202/558 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); called by muse, mutect2
- ANK1 | c.5012C>T p.S1671F | Missense Mutation (SNP) | VAF 188/514 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.668); called by muse, mutect2
- DHX32 | c.1966T>G p.S656A | Missense Mutation (SNP) | VAF 170/423 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, varscan2
- GSTA5 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 122/585 reads (21%) | called by muse, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 28/768 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- LYST | c.1508G>T p.R503L | Missense Mutation (SNP) | VAF 195/453 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PRICKLE1 | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 128/295 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- SPOCK3 | c.508G>T p.V170F | Missense Mutation (SNP) | VAF 127/327 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- USP28 | c.2084G>A p.W695* | Nonsense Mutation (SNP) | VAF 115/389 reads (30%) | called by muse, mutect2, varscan2
- FSIP2 | c.14205G>A p.L4735= | Silent (SNP) | VAF 186/403 reads (46%) | called by muse, mutect2, varscan2
- ZNF761 | c.1482C>T p.Y494= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- ARHGEF3 | c.-99C>T | 5'UTR (SNP) | VAF 3/10 reads (30%) | called by muse, varscan2
- DDX3X | c.149-67A>T | Intron (SNP) | VAF 40/65 reads (62%) | called by muse, mutect2, varscan2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 9/97 reads (9%) | catalogued as COSV99987084; called by muse, varscan2
- LARP4 | c.1334+88A>C | Intron (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 18/277 reads (6%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 4/43 reads (9%) | called by mutect2, varscan2
- TACO1 | c.*55C>T | 3'UTR (SNP) | VAF 39/95 reads (41%) | called by muse, mutect2, varscan2
- ZNF709 | c.*16C>T | 3'UTR (SNP) | VAF 72/267 reads (27%) | called by muse, varscan2
